Somatic mutation profile of tumor specimen MP2PRT-PAULMY-TMP1-A (aliquot MP2PRT-PAULMY-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAULMY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,365 days).
Specimen MP2PRT-PAULMY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c44a0329-3fff-4e64-99b9-53cbc14e2500.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAULMY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAULMY-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abe8688b-532d-4903-a855-e5ffea5cccf0

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 12, Silent 3, Frame Shift Ins 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SHOC2 | c.4A>G p.S2G | Missense Mutation (SNP) | VAF 98/211 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as rs267607048, CM095445, COSV54624833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AP3B2 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 115/275 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1397996908; called by muse, mutect2, varscan2
- B3GNTL1 | c.165T>A p.N55K | Missense Mutation (SNP) | VAF 123/307 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV57948856; called by muse, mutect2, varscan2
- CDC42BPA | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 87/195 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); catalogued as rs1413461960, COSV62003014; called by muse, mutect2, varscan2
- ETV1 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 147/338 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as rs772105404, COSV54136587; called by muse, mutect2, varscan2
- RASGRP2 | c.1046G>T p.S349I | Missense Mutation (SNP) | VAF 167/406 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV62449205; called by muse, mutect2, varscan2
- TMEM184A | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 123/348 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); catalogued as rs374204193; called by muse, mutect2, varscan2
- TSHZ3 | c.1349C>A p.T450N | Missense Mutation (SNP) | VAF 136/382 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1468902808; called by muse, mutect2, varscan2
- ATN1 | c.1669T>A p.S557T | Missense Mutation (SNP) | VAF 223/510 reads (44%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DOCK3 | c.711T>G p.F237L | Missense Mutation (SNP) | VAF 120/267 reads (45%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IGHV1-69 | c.348_349insGG p.R117Gfs*? | Frame Shift Ins (INS) | VAF 18/36 reads (50%) | called by pindel, varscan2
- IGHV3-53 | c.344_345insCTTCCT p.A115_R116insFL | In Frame Ins (INS) | VAF 4/35 reads (11%) | called by pindel, varscan2
- LAMB4 | c.248A>G p.Q83R | Missense Mutation (SNP) | VAF 151/352 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- METTL25 | c.352C>A p.Q118K | Missense Mutation (SNP) | VAF 125/319 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RPL5 | c.457dup p.T153Nfs*6 | Frame Shift Ins (INS) | VAF 112/322 reads (35%) | called by mutect2, pindel, varscan2
- ALDH1B1 | c.792C>T p.T264= | Silent (SNP) | VAF 141/170 reads (83%) | catalogued as rs749247146, COSV100890879; called by muse, mutect2, varscan2
- MYCN | c.1074G>A p.P358= | Silent (SNP) | VAF 225/497 reads (45%) | catalogued as rs760276350, COSV55258912; called by muse, mutect2, varscan2
- PAPPA2 | c.4965A>C p.P1655= | Silent (SNP) | VAF 84/280 reads (30%) | catalogued as rs774034066; called by mutect2, varscan2
